Gene-level copy-number profile of tumor specimen TCGA-50-6591-01A from TCGA case TCGA-50-6591, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 63.2 years (23,067 days).
Specimen TCGA-50-6591-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.8b940711-2f9d-4b43-9101-03acfddaaa28.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-50-6591-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a8318c49-0d10-43fc-8a54-14d592bfce80

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 2: 403; copy number 3: 17,204; copy number 4: 20,064; copy number 5: 9,541; copy number 6: 5,424; copy number 7: 4,955; copy number 8: 590; copy number 9: 697; copy number 10: 317; copy number 11: 315; copy number 12: 19; copy number 14: 128; copy number 20: 22; copy number 30: 131.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-50-6591-01A-11D-1752-01): tumor purity 0.9, ploidy 4.67, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:48,488,963–48,578,088, 5 genes: RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,629 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–27,662,883, 486 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr7:28,953,358–37,586,329, 165 genes, copy number 9 (broad region; genes not listed).
- chr7:38,977,909–57,837,046, 382 genes, copy number 9–30 (broad region; genes not listed).
- chr13:40,407,122–40,407,440, 1 gene, copy number 10: RN7SKP2.
- chr13:52,167,709–52,291,557, 1 gene, copy number 11 (within-gene range 8–11): AL158066.1.
- chr13:52,219,344–60,276,006, 74 genes, copy number 11 (broad region; genes not listed).
- chr13:79,389,534–79,667,344, 6 genes, copy number 10–12: RNA5SP33, RBM26-AS1, NDFIP2-AS1, NDFIP2, LINC01068, AL136442.1.
- chr19:40,048,757–40,808,418, 39 genes, copy number 9 (within-gene range 3–9): AC005614.2, ZNF780A, AC005614.1, VN1R96P, MAP3K10, TTC9B, CCNP, AKT2, AC118344.1, MIR641, RNU6-945P, C19orf47, Y_RNA, Y_RNA, PLD3, AC118344.2, MIR6796, HIPK4, PRX, SERTAD1, AC010271.2, SERTAD3, AC010271.1, BLVRB, Metazoa_SRP, SPTBN4, SHKBP1, LTBP4, NUMBL, COQ8B, RNU6-195P, ITPKC, C19orf54, SNRPA, MIA, MIA-RAB4B, RAB4B, RAB4B-EGLN2, AC008537.4.
- chr19:45,379,638–45,692,569, 18 genes, copy number 11 (within-gene range 3–11): PPP1R13L, POLR1G, ERCC1, MIR6088, FOSB, RTN2, PPM1N, VASP, OPA3, GPR4, EML2, MIR330, EML2-AS1, RN7SL836P, GIPR, MIR642A, MIR642B, SNRPD2.
- chr20:41,402,083–43,202,599, 15 genes, copy number 10 (within-gene range 6–10): CHD6, AL031667.2, AL031667.3, RPL12P11, RNU6-1018P, AL133229.1, AL049812.2, AL049812.1, AL049812.3, PTPRT, AL035666.1, AL031656.1, PTPRT-AS1, RN7SKP100, AL021395.1.
- chr20:46,008,908–64,313,132, 442 genes, copy number 10–14 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
